Somatic mutation profile of tumor specimen 0DNE0N from CCDI case PBCBNI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 11.1 years (4,041 days).
Specimen 0DNE0N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e8ea300-8d14-47b3-8e3a-64317d7d37c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNE0S (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45d515fd-b11f-450a-8296-39e18c79367f

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTN4 | c.2375C>T p.T792M | Missense Mutation (SNP) | VAF 120/255 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs952348369, COSV61876508; called by muse, mutect2, varscan2
- EML3 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 109/354 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as rs1352985280, COSV53881379; called by muse, mutect2, varscan2
- NRXN1 | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 242/555 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs200325059, COSV58461654; called by muse, mutect2, varscan2
- PLA2G2F | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 185/454 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs370472527; called by muse, mutect2, varscan2
- TGM4 | c.689T>C p.I230T | Missense Mutation (SNP) | VAF 248/552 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs370631370; called by muse, mutect2
- PGAP6 | c.778_779dup p.A261Vfs*21 | Frame Shift Ins (INS) | VAF 111/308 reads (36%) | called by mutect2, pindel, varscan2
- ZGRF1 | c.5890T>A p.Y1964N | Missense Mutation (SNP) | VAF 149/349 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF382 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 192/432 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
